CPTAC case C3N-01012 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eac6ceca-d905-4a4d-ae89-ea533370aea8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1947; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 71.1 years (25,953 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,824 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,824 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 27; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 378 days (1.0 years); Disease response: Complete Response.
- Days to follow up: 616 days (1.7 years); Disease response: Complete Response.
- Days to follow up: 1,064 days (2.9 years); Disease response: Complete Response.
- Days to follow up: 1,352 days (3.7 years); Disease response: Complete Response.
- Days to follow up: 1,824 days (5.0 years); Disease response: Complete Response.

Other clinical attributes
- Weight: 84 kg; Height: 175 cm; BMI: 27.43.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 37.5; Cigarettes per day: 15; Tobacco smoking onset year: 1968; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 54.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01012-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 98 mg; Time between excision and freezing: 48 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01012-21: Section location: Head; Percent tumor nuclei: 10; Percent necrosis: 0.
- Sample C3N-01012-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 104 mg; Time between excision and freezing: 48 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01012-22: Section location: Head; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3N-01012-30: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
